MMRF case MMRF_1371 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/20839430-0a98-44ba-bc76-5d40c4bf8796

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.2 years (22,355 days); ISS stage: I; Days to last known disease status: 1,448 days (4.0 years); Days to last follow up: 1,448 days (4.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 264 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 250 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 264 days; Days to treatment end: 264 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 292 days; Days to treatment end: 292 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 404 days (1.1 years); Days to treatment end: 819 days (2.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 819 days (2.2 years); Days to treatment end: 911 days (2.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 911 days (2.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 1): M Protein 3.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.784 mg/dL; Immunoglobulin G 42.1 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.8 µg/mL; Hemoglobin 8 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 10.5 g/dL; Glucose 4.84 mmol/L; C-Reactive Protein 0.34 mg/dL.
- Day 92 (ECOG 1): Immunoglobulin G 43.1 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.05 mmol/L; Albumin 33 g/L; Total Protein 9.3 g/dL; Glucose 4.68 mmol/L.
- Day 176 (ECOG 1): M Protein 1.51 g/dL; Immunoglobulin G 23.4 g/L; Immunoglobulin M 20.9 g/L; Beta 2 Microglobulin 0.21 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 7.8 g/dL; Glucose 4.62 mmol/L.
- Day 267 (ECOG 1): M Protein 0.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.816 mg/dL; Immunoglobulin G 12.4 g/L; Beta 2 Microglobulin 0.21 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 4.46 mmol/L.
- Day 351 (ECOG 1): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.951 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 10 g/L; Beta 2 Microglobulin 0.25 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.51 mmol/L.
- Day 440 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.781 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.888 mg/dL; Immunoglobulin G 9.82 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 0.25 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 4.68 mmol/L.
- Day 560 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 8.98 g/L; Beta 2 Microglobulin 0.34 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 6.49 mmol/L.
- Day 650 (ECOG 0): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 9.45 g/L; Beta 2 Microglobulin 0.31 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.46 mmol/L.
- Day 734 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 10.2 g/L; Beta 2 Microglobulin 0.36 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 3.63 mmol/L.
- Day 819 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 10.1 g/L; Beta 2 Microglobulin 0.34 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 904 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 9.98 g/L; Immunoglobulin A 3.07 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 0.3 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.84 mmol/L.
- Day 988 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 3.02 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 0.31 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 5.89 mmol/L.
- Day 1,097 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 3.1 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 0.33 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.45 mmol/L.
- Day 1,181 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 9.78 g/L; Immunoglobulin A 2.59 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 0.3 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 1,272 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 2.93 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 0.31 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 5.45 mmol/L.
- Day 1,356 (ECOG 0): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 2.87 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 0.33 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 5.34 mmol/L.
- Day 1,448 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 9.54 g/L; Immunoglobulin A 2.71 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 0.3 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -10: Weight: 99 kg; Height: 191 cm.

Biospecimens (2 samples)
- Sample MMRF_1371_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_1371_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
